Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VK, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VK-01A (Primary Tumor).

[page 1 of 4]
Neck
1d Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Bilateral thyroid nodules.

Specimens Submitted:

- 1: Pretracheal tissue
- 2: Delphian node
- 3: To rule out right lower parathyroid (fs)
- 4: Total thyroidectomy
- 5: Tissue right lower pole of thyroid

0010-00000040-0000-0000-0000-0000-0000

DIAGNOSIS:

1. **Pretracheal tissue; biopsy:**
- One benign lymph node with crush and cautery artifact (0/1)
2. **Delphian node; excision:**
- Benign fibroadipose tissue
- No lymph node identified
3. **Right lower parathyroid; biopsy:**
- Fragment of benign hyperplastic thyroid tissue

4. **Total thyroidectomy:**

Tumor Type:

Papillary carcinoma, follicular variant *99% follicular variant per BS /w*

Mitotic Activity:

Not identified

ICD-O-3

Tumor Necrosis:

Not identified

carcinoma, papillary, follicular variant
8340/3

Tumor Location:

Right lobe

Site: thyroid, NOS

Tumor Size:

Greatest diameter is 1.0 cm.

C73.9 5-2-12
R0

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Focal extrathyroidal extension into the fibroadipose tissue of papillary microcarcinoma (left lobe, 0.8 cm)

Surgical Margins:

Free of tumor

[page 2 of 4]
Tumor Multicentricity:

Papillary microcarcinoma, three foci (left lobe: 0.8 cm and 0.7 cm in greatest dimension; right lobe: less than 0.1 cm in greatest dimension)

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

Lymph Nodes:

One benign lymph node (0/1)

Comment: Immunohistochemistry was performed on one hyperplastic nodule with trabecular growth pattern showing positive staining for thyroglobulin and negative staining for calcitonin, chromogranin and synaptophysin.

5. Thyroid, right lower pole; excision:

- Fragments of benign thyroid tissue with nodular hyperplasia

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	THYROG	
	CALC	
	CHR	
	SYN	
	IMM RECUT	
	NEG CONT	

Gross Description:

1). The specimen is received in formalin, labeled "Pretracheal tissue" and consists of a 1.6 x 1.0 x 0.4 cm fragment of tan soft tissue. Entirely submitted.

Summary of sections:

U – undesignated

2). The specimen is received in formalin, labeled "Delphian node" and consists of 1.1 x 0.7 x 0.5cm lymph node which is bisected and entirely submitted.

Summary of sections:

BLN – bisected lymph node

3). The specimen is received fresh for frozen section consultation, labeled "to rule out right lower parathyroid" and consists of a tan soft tissue fragment measuring 0.4 x 0.4 x 0.2 cm. Entirely submitted for frozen section.

[page 3 of 4]
Summary of sections:
FSC - frozen section control

4). The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid weighing 12.5 g. The right lobe measures 5 x 3 x 2 cm, the left lobe measures 4 x 2 x 1 cm and the isthmus measures 1 x 1 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals 3 tan, well circumscribed nodules as follows: inferior right lobe (RN, 1 x 1 x 1 cm), mid left lobe (LN1, 0.8 x 0.5 x 0.5 cm), and inferior left lobe (LN2, 0.5 x 0.4 x 0.4 cm). The remaining thyroid parenchyma is red tan and beefy. Representative sections of RN are submitted for The remaining tissue is serially sectioned and entirely submitted.

Summary of sections
RN - right lobe nodule
LN1- mid left lobe nodule
LN2- inferior left lobe nodule
RL - right lobe
LL - left lobe
IS - isthmus

5). The specimen is received in formalin labeled "Tissue right lower pole of thyroid." It consists of a piece of brown tan thyroid parenchyma measuring 1.0 x 0.8 x 0.7 cm. The outer surface of the specimen is inked black. The specimen is sectioned and submitted entirely.

Summary of sections:
U - undesignated

Summary of Sections:
Part 1: Pretracheal tissue

Block	Sect. Site	PCs
1	U	1

Part 2: Delphian node

Block	Sect. Site	PCs
1	BLN	1

Part 3: To rule out right lower parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 4: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
1	LL	2
4	LN1	4
3	LN2	3
7	RL	7
3	RN	3

Part 5: Tissue right lower pole of thyroid

Block	Sect. Site	PCs
1	U	1

[page 4 of 4]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

3. Frozen section diagnosis: To rule out right lower parathyroid (fs): Thyroid tissue
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file 4dc6bec2-ccc3-47ea-8589-f2a8cc3018fa (TCGA-DJ-A3VK.08906F4D-8930-4EAA-B9A6-1C5A7DB6E62B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).